Somatic mutation profile of tumor specimen TARGET-30-PASFNY-01A (aliquot TARGET-30-PASFNY-01A-01D) from TARGET case TARGET-30-PASFNY, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.6 years (945 days).
Specimen TARGET-30-PASFNY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe76680a-e1a7-42eb-b118-0b7c3c3ce973.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASFNY-10A (Blood Derived Normal), aliquot TARGET-30-PASFNY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc6666e6-13dc-4248-8b21-1682ff2dae92

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.12663G>T p.M4221I | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.64); catalogued as COSV60909457; called by muse, mutect2, varscan2
- ALMS1 | c.5379C>G p.D1793E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV52514084; called by muse, mutect2
- EPHX3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.369); catalogued as COSV55654758; called by muse, mutect2, varscan2
- LMOD1 | c.979A>G p.N327D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs756949838, COSV66172017; called by muse, mutect2, varscan2
- LRP2BP | c.1044G>T p.*348Yext*12 | Nonstop Mutation (SNP) | VAF 28/130 reads (22%) | catalogued as COSV53012132, COSV53016439; called by muse, mutect2, varscan2
- MNDA | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 28/46 reads (61%) | catalogued as COSV63740111; called by muse, mutect2, varscan2
- NLRP9 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60460557; called by muse, mutect2, varscan2
- RAD50 | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV54748508; called by muse, mutect2, varscan2
- SATL1 | c.21G>T p.W7C (on ENST00000395409; = p.W194C on NM_001012980.2) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.429); catalogued as COSV60575705, COSV60576101; called by muse, mutect2, varscan2
- TXNL1 | c.677A>C p.K226T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as COSV54178514; called by muse, mutect2, varscan2
- PRSS1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- MYH6 | c.4587G>A p.E1529= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1302804356, COSV62447980, COSV62448413; called by muse, mutect2, varscan2
- OR52E6 | c.855T>C p.P285= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV61431507; called by muse, mutect2, varscan2
- POLK | c.174G>A p.K58= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs758702741, COSV54032794; called by muse, mutect2, varscan2
- TCIRG1 | c.2130C>A p.S710= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as CD1210359, COSV55834687; called by muse, mutect2, varscan2
- HAUS7 | c.960+517C>A | Intron (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
